Surgical pathology report (de-identified scan), TCGA case TCGA-14-1454, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1454-01A (Primary Tumor).

Section 1 of 1: Anatomic Pathology Report
Auth [REDACTED] EMR EVENT Id: [REDACTED]

Patient: [REDACTED] Accession Number: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Submitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT TEMPORAL BRAIN LESION, BIOPSY, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. LEFT TEMPORAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).

TCGA-14-1454

Specimen:

1. Left temporal brain lesion.
2. Left temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Brain tumor.

GROSS DESCRIPTION:

Two specimens are received, both labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation, labeled "left temporal brain lesion." The specimen consists of multiple fragments of tan-red tissue measuring in aggregate 2.0 x 1.0 x 0.4 cm. A representative section of the specimen is submitted for frozen tissue diagnosis, and the contents of the cryoblock is submitted in cassette "FS1A." The remainder of the tissue is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "left temporal brain lesion." The specimen consists of multiple pieces of tan-red tissue measuring in aggregate 4.0 x 1.5 x 1.2 cm. Representative sections are submitted in one cassette labeled "2A."

NOTES/OPERATIVE CONSULTATION:

FS1A: BRAIN, LEFT TEMPORAL (FROZEN SECTION): GLIOBLASTOMA.

Source: NCI Genomic Data Commons file 4879f07a-a0c4-466b-a651-abd49bdfc82f (TCGA-14-1454.F8FA518D-F367-490E-9F74-15A6F822F7B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).